Somatic mutation profile of tumor specimen TCGA-SR-A6MT-01A (aliquot TCGA-SR-A6MT-01A-11D-A35I-08) from TCGA case TCGA-SR-A6MT, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 57.3 years (20,944 days).
Specimen TCGA-SR-A6MT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5e08ff6-6087-44a0-959d-340630b0b3e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SR-A6MT-10A (Blood Derived Normal), aliquot TCGA-SR-A6MT-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ad4af58-cca8-461d-a483-939cb44780a2

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HPS4 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61104037; called by muse, mutect2
- KCNH6 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs766766661, COSV59001216; called by muse, mutect2, varscan2
- RSBN1L | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as COSV58511509; called by muse, mutect2
- ARFGEF1 | c.2808_2810del p.F936_T937delinsL | In Frame Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel
- FXR1 | c.23T>G p.V8G | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KCNT2 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEPTIN8 | c.462C>G p.L154= | Silent (SNP) | VAF 7/156 reads (4%) | called by muse, mutect2
